Somatic mutation profile of tumor specimen TCGA-LN-A9FQ-01A (aliquot TCGA-LN-A9FQ-01A-31D-A387-09) from TCGA case TCGA-LN-A9FQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 62.2 years (22,717 days).
Specimen TCGA-LN-A9FQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fe8c4f1-9eb5-4080-9403-41677192d30f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A9FQ-10A (Blood Derived Normal), aliquot TCGA-LN-A9FQ-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8075a93a-1e0e-4e24-bfed-e653111ed01d

The open-access MAF lists 101 somatic variants for this specimen: 76 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 23, Nonsense Mutation 3, Intron 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.2810+1G>A p.X937_splice | Splice Site (SNP) | VAF 16/43 reads (37%) | catalogued as rs199954546, CS080679, COSV50326635; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 26/44 reads (59%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP002512.3 | c.76T>C p.F26L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs775746409; called by muse, mutect2, varscan2
- CACNA1S | c.3538G>A p.D1180N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775845281; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCNC | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58334803; called by muse, mutect2
- CDC25B | c.1072G>A p.E358K (on ENST00000245960 / NM_021873.3; = p.E344K on NM_004358.4) | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as COSV55659993; called by muse, mutect2, varscan2
- DIDO1 | c.3649C>T p.R1217* | Nonsense Mutation (SNP) | VAF 51/126 reads (40%) | catalogued as COSV56620631; called by muse, mutect2, varscan2
- EIF3A | c.3926C>A p.S1309Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs1345089132; called by muse, mutect2, varscan2
- FGFR4 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1326935512, COSV52801086; called by muse, mutect2, varscan2
- GLB1L2 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 67/128 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs201456055, COSV60277575; called by muse, mutect2, varscan2
- GON4L | c.4411G>A p.D1471N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs748290334; called by muse, mutect2, varscan2
- HAUS7 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 34/47 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs201262645; called by muse, mutect2, varscan2
- KRT1 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV52869957; called by muse, mutect2, varscan2
- LAMB3 | c.3152G>A p.R1051Q | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs751750658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIMA1 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs770526598, COSV57965474; called by muse, mutect2, varscan2
- MAP4K3 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417129709; called by mutect2, varscan2
- MFSD13A | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767309455, COSV53267838; called by muse, mutect2, varscan2
- MMD2 | c.643G>A p.G215R (on ENST00000404774 / NM_001100600.2; = p.G191R on NM_198403.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs375097927; called by muse, mutect2, varscan2
- NBEAL2 | c.7865G>A p.R2622H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs1299423017, COSV52754335; called by muse, mutect2, varscan2
- NPAS3 | c.2516C>A p.A839D (on ENST00000356141 / NM_001164749.2; = p.A807D on NM_022123.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV60862159; called by muse, mutect2, varscan2
- OTOL1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs762554496, COSV60008398; called by muse, mutect2, varscan2
- PCLO | c.13019C>G p.T4340S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.566); catalogued as COSV61670518; called by muse, mutect2, varscan2
- POLE | c.6073G>A p.V2025M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs995579204, COSV57684467; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRG2 | c.166G>C p.E56Q | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55870021; called by muse, mutect2, varscan2
- RNF148 | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs368198874; called by muse, mutect2, varscan2
- SENP6 | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0.241); catalogued as COSV100894306; called by muse, mutect2, varscan2
- SIVA1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as rs746975954; called by muse, mutect2, varscan2
- SLC7A9 | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as rs772994838; called by muse, mutect2, varscan2
- SON | c.5182A>G p.I1728V | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs1237269717, COSV51656973; called by muse, mutect2, varscan2
- SPTBN4 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV100152616; called by muse, mutect2, varscan2
- TUBB6 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as rs866985204; called by muse, mutect2, varscan2
- UBQLN2 | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs1444745417; called by muse, mutect2, varscan2
- XPO1 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV68946853; called by muse, mutect2, varscan2
- AAMP | c.396C>A p.G132= | Splice Region (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- ADAMTS13 | c.2201C>G p.P734R | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ADAMTS19 | c.3500C>G p.T1167S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRV1 | c.8512C>G p.Q2838E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALPK2 | c.6302A>G p.K2101R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APBB2 | c.1307C>T p.P436L (on ENST00000295974 / NM_001166050.2; = p.P437L on NM_004307.2) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOL3 | c.584G>C p.G195A (on ENST00000349314 / NM_145640.2; = p.G124A on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ARHGAP24 | c.1597G>A p.D533N (on ENST00000395184 / NM_001025616.3; = p.D440N on NM_031305.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ASAP1 | c.21G>C p.R7S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ATXN2L | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- BANK1 | c.2170G>C p.D724H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DPF2 | c.626A>G p.Y209C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GABRB1 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | called by mutect2, varscan2
- H2BC8 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- IKZF1 | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IREB2 | c.430A>T p.N144Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLRC4 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- LORICRIN | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- LPA | c.4790G>T p.S1597I | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- LRRIQ1 | c.3922C>T p.P1308S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MFN2 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MFSD10 | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MRC1 | c.2082G>T p.E694D | Missense Mutation (SNP) | VAF 106/170 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, varscan2
- NAV1 | c.1412G>C p.S471T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- NFIX | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NR2C2 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- OR51M1 | c.799A>T p.M267L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- PDE6C | c.1524A>T p.E508D | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- PELI2 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCLT1 | c.1490A>T p.N497I | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- SLC10A4 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by mutect2, varscan2
- SLC25A45 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STEAP4 | c.256T>G p.Y86D | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TBX20 | c.1148T>C p.I383T | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TCHH | c.3909G>T p.E1303D | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2
- TUT4 | c.2703T>G p.D901E | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- WWP1 | c.296T>A p.I99K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZFHX4 | c.9668C>T p.S3223L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- ZNF234 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF410 | c.971C>A p.S324Y | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF714 | c.1430G>T p.G477V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DCDC1 | c.156T>C p.D52= | Silent (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- DCTN1 | c.1824G>A p.V608= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.5559G>T p.V1853= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- EHD2 | c.1179C>T p.L393= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs146746938; called by muse, mutect2, varscan2
- EXOC1 | c.513C>T p.I171= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as rs750179198; called by muse, mutect2, varscan2
- FTHL17 | c.33G>A p.Q11= | Silent (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- HSD17B14 | c.762G>T p.G254= | Silent (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- ISL2 | c.198C>T p.C66= | Silent (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- MEOX2 | c.435G>A p.A145= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs1178565718; called by muse, mutect2, varscan2
- MS4A1 | c.90C>T p.L30= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs900234715, COSV100619427; called by muse, mutect2, varscan2
- NBAS | c.924C>T p.V308= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs774810902; called by muse, mutect2, varscan2
- PKHD1 | c.11133G>A p.G3711= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs760027300; called by muse, mutect2, varscan2
- PRKCH | c.1623C>T p.G541= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs750561562; called by muse, mutect2, varscan2
- RAP1GAP2 | c.2010C>T p.F670= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1042457722; called by muse, mutect2
- RIC8B | c.363G>C p.L121= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- RUSC1 | c.1605C>G p.L535= (on ENST00000368352 / NM_001105203.2; = p.L66= on NM_014328.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1242216189, COSV52741083; called by muse, mutect2, varscan2
- SNX29 | c.1611C>T p.L537= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV60050286; called by muse, mutect2, varscan2
- STYXL2 | c.1977G>T p.L659= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs1316197678; called by muse, mutect2, varscan2
- SUGP1 | c.354C>T p.T118= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as rs775970861; called by muse, mutect2, varscan2
- TGM1 | c.1764G>A p.A588= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as rs750237191; ClinVar: likely benign; called by muse, mutect2, varscan2
- VPS45 | c.1500G>A p.Q500= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV64888657; called by muse, mutect2, varscan2
- ZC3H12B | c.372G>A p.Q124= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- ZNF287 | c.1185G>A p.S395= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs142954560; called by muse, mutect2, varscan2
- CASR | c.1378-6257G>A | Intron (SNP) | VAF 13/104 reads (13%) | catalogued as COSV56140195; called by muse, mutect2, varscan2
- MBNL1 | c.174+40244C>T | Intron (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99221015; called by muse, mutect2, varscan2
